Gene-level copy-number profile of tumor specimen TCGA-13-0883-01A from TCGA case TCGA-13-0883, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,395 days).
Specimen TCGA-13-0883-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ceabd0be-fcb9-4fc3-9817-00452e386182.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0883-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38ac6ed9-0a6a-4580-bb98-f8f7830388a1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 15,376; copy number 3: 17,720; copy number 4: 16,593; copy number 5: 4,107; copy number 6: 1,639; copy number 7: 1,282; copy number 8: 636; copy number 11: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0883-01A-02D-0399-01): tumor purity 0.72, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,208 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:91,500,851–91,644,082, 4 genes, copy number 8: CDC7, WDR82P2, AL714022.1, HSP90B3P.
- chr2:183,607,442–199,750,341, 182 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr5:43,874,367–45,895,970, 17 genes, copy number 7: AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:12,716,554–23,649,774, 135 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr12:66,767–25,959,765, 671 genes, copy number 8–11 (broad region; genes not listed).
- chr12:28,133,249–42,717,120, 199 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,136. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
